Somatic mutation profile of tumor specimen SM-JU33R (aliquot 7316UP-1110) from CPTAC case C317832, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Parietal lobe; Tumor grade: G4.
Specimen SM-JU33R: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 997fa754-c386-4f27-b344-7efa59b60cb9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 1105209 (Blood Derived Normal), aliquot 7316UP-435-1105209; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bbedbe0b-d604-4310-a523-eb457a19ccbb

The open-access MAF lists 121 somatic variants for this specimen: 77 protein-altering or splice-affecting, 23 silent, 21 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 66, Silent 23, Intron 9, RNA 7, Frame Shift Del 4, Nonsense Mutation 4, Splice Site 2, 3'UTR 2, 5'UTR 1, Splice Region 1, 5'Flank 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 42/618 reads (7%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- ABCA5 | c.1693G>A p.D565N | Missense Mutation (SNP) | VAF 37/106 reads (35%) | SIFT tolerated (1); PolyPhen possibly damaging (0.454); catalogued as COSV101201270; called by muse, mutect2, varscan2
- ABCA9 | c.3625C>A p.P1209T | Missense Mutation (SNP) | VAF 32/61 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as COSV100382512, COSV60631257; called by muse, mutect2, varscan2
- ABTB1 | c.1159G>A p.V387M (on ENST00000232744 / NM_172027.3; = p.V245M on NM_032548.3) | Missense Mutation (SNP) | VAF 130/316 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.009); catalogued as rs373702607; called by muse, mutect2, varscan2
- ADARB2 | c.2108C>A p.A703E | Missense Mutation (SNP) | VAF 105/146 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67182195; called by muse, mutect2, varscan2
- C10orf71 | c.469C>A p.R157S | Missense Mutation (SNP) | VAF 110/148 reads (74%) | SIFT tolerated (0.47); PolyPhen benign (0.013); catalogued as rs754197819, COSV60504037; called by muse, mutect2, varscan2
- CASP10 | c.1558G>A p.V520I | Missense Mutation (SNP) | VAF 119/290 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs141197114; called by muse, mutect2, varscan2
- CC2D1A | c.2303G>A p.R768Q | Missense Mutation (SNP) | VAF 47/203 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs749453820; called by muse, mutect2, varscan2
- CD96 | c.218C>T p.P73L | Missense Mutation (SNP) | VAF 104/241 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs1035836810, COSV51917150; called by muse, mutect2, varscan2
- CFAP52 | c.811G>A p.G271R | Missense Mutation (SNP) | VAF 44/125 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs140921334; called by muse, mutect2, varscan2
- CTR9 | c.694G>A p.V232M | Missense Mutation (SNP) | VAF 52/183 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs754637023, COSV63728462; called by muse, mutect2, varscan2
- DMBX1 | c.37G>A p.A13T | Missense Mutation (SNP) | VAF 35/274 reads (13%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.52); catalogued as rs537159573, COSV63602702; called by muse, mutect2, varscan2
- DNAH11 | c.6005G>A p.R2002Q | Missense Mutation (SNP) | VAF 147/562 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as rs755849132; called by muse, mutect2, varscan2
- FKBP5 | c.52G>C p.V18L | Missense Mutation (SNP) | VAF 38/153 reads (25%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as rs1219431414; called by muse, mutect2, varscan2
- GIN1 | c.1472C>A p.T491K | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.018); catalogued as COSV67537797; called by muse, mutect2, varscan2
- GLRA3 | c.1054C>T p.R352* | Nonsense Mutation (SNP) | VAF 92/123 reads (75%) | catalogued as rs766770260; called by muse, mutect2, varscan2
- GRB7 | c.287G>A p.R96H | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.55); catalogued as rs371037902, COSV58450006; called by muse, mutect2, varscan2
- GREB1L | c.1052G>A p.R351H | Missense Mutation (SNP) | VAF 114/256 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs371959545, COSV52552089; called by muse, mutect2, varscan2
- HTR3A | c.571C>T p.R191C | Missense Mutation (SNP) | VAF 83/503 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs918546404, COSV55471345, COSV55471669; called by muse, mutect2, varscan2
- MAL2 | c.59C>T p.P20L | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs757642924; called by muse, mutect2, varscan2
- MARCKS | c.980del p.P327Qfs*42 | Frame Shift Del (DEL) | VAF 54/177 reads (31%) | catalogued as rs770972906; called by mutect2, pindel, varscan2
- MCIDAS | c.587C>T p.A196V | Missense Mutation (SNP) | VAF 88/230 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1347065948; called by muse, mutect2, varscan2
- MGAT4B | c.790G>A p.V264M | Missense Mutation (SNP) | VAF 94/248 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs749104766, COSV52976664; called by muse, mutect2, varscan2
- NAALADL1 | c.593G>A p.R198H | Missense Mutation (SNP) | VAF 42/85 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs375401003; called by muse, mutect2, varscan2
- NKRF | c.614G>A p.R205H | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.093); catalogued as rs371790847; called by muse, mutect2, varscan2
- OR6S1 | c.43G>A p.V15I | Missense Mutation (SNP) | VAF 45/76 reads (59%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs780340636, COSV57837458; called by muse, mutect2, varscan2
- PCDHGB2 | c.1546G>A p.A516T | Missense Mutation (SNP) | VAF 237/584 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV53926229; called by muse, mutect2, varscan2
- PIK3C2G | c.2661G>C p.K887N (on ENST00000676171; = p.K846N on NM_004570.5) | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1446479359; called by muse, mutect2
- PITPNM2 | c.2165T>C p.L722P | Missense Mutation (SNP) | VAF 14/299 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV99758216; called by muse, mutect2
- PRDM9 | c.415T>G p.L139V | Missense Mutation (SNP) | VAF 12/238 reads (5%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as COSV57002327; called by muse, mutect2
- PTEN | c.320A>G p.D107G | Missense Mutation (SNP) | VAF 13/234 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs786204858, CM142082, COSV64290655, COSV64294121; called by muse, mutect2
- RIMS2 | c.1789T>A p.S597T (on ENST00000666250 / NM_001348490.2; = p.S405T on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 48/129 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.022); catalogued as rs370262056; called by muse, mutect2, varscan2
- RYR1 | c.10595T>A p.L3532H | Missense Mutation (SNP) | VAF 201/680 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs748378336; called by muse, mutect2, varscan2
- SCN10A | c.5376G>T p.L1792F | Missense Mutation (SNP) | VAF 99/227 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs1488076050; called by muse, mutect2, varscan2
- SLC1A2 | c.575C>T p.T192M | Missense Mutation (SNP) | VAF 44/100 reads (44%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.666); catalogued as rs146728719; called by muse, mutect2, varscan2
- SLC5A5 | c.803G>A p.R268H | Missense Mutation (SNP) | VAF 149/580 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs527624357; called by muse, mutect2, varscan2
- SPTA1 | c.812+1G>T p.X271_splice | Splice Site (SNP) | VAF 171/595 reads (29%) | catalogued as rs1421295482; called by muse, mutect2, varscan2
- UGT2A3 | c.1369C>T p.R457* | Nonsense Mutation (SNP) | VAF 105/217 reads (48%) | catalogued as rs267600216, COSV52359885, COSV52360393; called by muse, mutect2, varscan2
- ZBED9 | c.3223C>T p.R1075* | Nonsense Mutation (SNP) | VAF 118/408 reads (29%) | catalogued as rs143546833; called by muse, mutect2, varscan2
- ZNF670 | c.721C>T p.R241C | Missense Mutation (SNP) | VAF 42/128 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.47); catalogued as rs369428325; called by muse, mutect2, varscan2
- ADGRV1 | c.8770T>G p.L2924V | Missense Mutation (SNP) | VAF 60/166 reads (36%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.679); called by muse, mutect2, varscan2
- ALPK3 | c.2000C>A p.A667E | Missense Mutation (SNP) | VAF 101/247 reads (41%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CSK | c.965T>C p.V322A | Missense Mutation (SNP) | VAF 40/298 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- DIP2A | c.1591T>C p.S531P | Missense Mutation (SNP) | VAF 19/298 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); called by muse, mutect2
- DNAH2 | c.9972C>A p.F3324L | Missense Mutation (SNP) | VAF 67/182 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- DNAH6 | c.6498A>C p.L2166F | Missense Mutation (SNP) | VAF 27/181 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.733); called by muse, varscan2
- FLII | c.1851T>A p.Y617* | Nonsense Mutation (SNP) | VAF 67/145 reads (46%) | called by muse, mutect2, varscan2
- GCNT1 | c.376T>C p.S126P | Missense Mutation (SNP) | VAF 41/121 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GPR149 | c.112del p.C38Afs*2 | Frame Shift Del (DEL) | VAF 141/379 reads (37%) | called by mutect2, pindel, varscan2
- GPR6 | c.608C>A p.P203H | Missense Mutation (SNP) | VAF 51/414 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IFRD2 | c.311C>A p.A104D | Missense Mutation (SNP) | VAF 115/295 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.697); called by muse, mutect2, varscan2
- JCAD | c.203A>G p.D68G | Missense Mutation (SNP) | VAF 77/227 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.344); called by muse, mutect2, varscan2
- KCTD20 | c.653A>G p.D218G | Missense Mutation (SNP) | VAF 15/141 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LRP1B | c.11058C>G p.C3686W | Missense Mutation (SNP) | VAF 75/213 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRRC3 | c.397del p.L133Wfs*28 | Frame Shift Del (DEL) | VAF 57/161 reads (35%) | called by mutect2, pindel, varscan2
- MAGEC1 | c.1952C>A p.P651H | Missense Mutation (SNP) | VAF 38/47 reads (81%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.54); called by muse, mutect2, varscan2
- MAGEL2 | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- MAP4K2 | c.1407+8T>C | Splice Region (SNP) | VAF 7/134 reads (5%) | called by muse, mutect2
- MEX3B | c.208G>A p.V70M | Missense Mutation (SNP) | VAF 16/254 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MGRN1 | c.530A>G p.K177R | Missense Mutation (SNP) | VAF 80/198 reads (40%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- MYOCD | c.971+3_971+6del p.X324_splice | Splice Site (DEL) | VAF 46/137 reads (34%) | called by pindel, varscan2
- NCOA7 | c.800G>T p.G267V | Missense Mutation (SNP) | VAF 12/201 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- NEFM | c.2383T>C p.S795P | Missense Mutation (SNP) | VAF 14/263 reads (5%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.367); called by muse, mutect2
- NPHS2 | c.1057C>T p.P353S | Missense Mutation (SNP) | VAF 208/452 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR10G7 | c.419G>A p.C140Y | Missense Mutation (SNP) | VAF 122/297 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- OR10P1 | c.389C>T p.P130L | Missense Mutation (SNP) | VAF 72/174 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR2M3 | c.620T>C p.I207T | Missense Mutation (SNP) | VAF 22/571 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.328); called by muse, mutect2
- PCDH11Y | c.3088G>C p.V1030L (on ENST00000400457 / NM_032973.2; = p.V1019L on NM_032971.3) | Missense Mutation (SNP) | VAF 303/338 reads (90%) | SIFT tolerated (0.28); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- POSTN | c.2483G>C p.R828T | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.054); called by muse, mutect2
- SCN11A | c.2696T>C p.I899T | Missense Mutation (SNP) | VAF 105/284 reads (37%) | SIFT tolerated (0.51); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SLC12A9 | c.1405A>G p.M469V | Missense Mutation (SNP) | VAF 86/192 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.456); called by muse, mutect2, varscan2
- STEAP3 | c.28A>G p.I10V | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.012); called by muse, mutect2
- TERB2 | c.203A>G p.Y68C | Missense Mutation (SNP) | VAF 12/238 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- TNPO2 | c.1190del p.P397Hfs*40 | Frame Shift Del (DEL) | VAF 54/261 reads (21%) | called by mutect2, pindel, varscan2
- TTN | c.1843G>C p.V615L (on ENST00000591111; = p.V569L on NM_003319.4) | Missense Mutation (SNP) | VAF 108/271 reads (40%) | PolyPhen benign (0.075); called by muse, mutect2, varscan2
- ZNF311 | c.47A>G p.Q16R | Missense Mutation (SNP) | VAF 101/245 reads (41%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZZEF1 | c.6934T>C p.C2312R | Missense Mutation (SNP) | VAF 74/412 reads (18%) | SIFT tolerated (0.51); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ACSF2 | c.942T>C p.G314= | Silent (SNP) | VAF 44/241 reads (18%) | called by muse, mutect2, varscan2
- ADCY2 | c.78G>A p.L26= | Silent (SNP) | VAF 21/334 reads (6%) | called by muse, mutect2
- AFTPH | c.2805C>T p.D935= (on ENST00000238855 / NM_203437.3; = p.D908= on NM_017657.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 48/103 reads (47%) | catalogued as rs554022165, COSV53218290; called by muse, mutect2, varscan2
- BMP5 | c.594C>T p.F198= | Silent (SNP) | VAF 112/283 reads (40%) | catalogued as rs1401963889; called by muse, mutect2, varscan2
- CACNA1B | c.936C>T p.T312= | Silent (SNP) | VAF 23/101 reads (23%) | called by muse, mutect2, varscan2
- CEACAM7 | c.120C>T p.V40= | Silent (SNP) | VAF 41/116 reads (35%) | catalogued as rs147314898; called by muse, mutect2
- DIDO1 | c.5859T>C p.P1953= | Silent (SNP) | VAF 26/427 reads (6%) | called by muse, mutect2
- DNMT3A | c.1707G>A p.P569= | Silent (SNP) | VAF 103/214 reads (48%) | catalogued as rs749106325, COSV53071322, COSV99262646; called by muse, mutect2, varscan2
- GPR141 | c.90C>T p.G30= | Silent (SNP) | VAF 55/254 reads (22%) | catalogued as rs368456046; called by muse, varscan2
- GPRC6A | c.708C>T p.N236= | Silent (SNP) | VAF 65/147 reads (44%) | catalogued as rs772554360, COSV59951415; called by muse, mutect2, varscan2
- HCAR2 | c.825G>A p.A275= | Silent (SNP) | VAF 87/386 reads (23%) | catalogued as rs202067823, COSV61024215; called by muse, mutect2, varscan2
- HCAR3 | c.825G>A p.A275= | Silent (SNP) | VAF 32/119 reads (27%) | catalogued as rs774009296, COSV63671744; called by muse, mutect2, varscan2
- HECW1 | c.2331C>T p.S777= | Silent (SNP) | VAF 28/198 reads (14%) | catalogued as rs200544206, COSV101223118; called by muse, mutect2, varscan2
- KRTAP26-1 | c.261C>T p.Y87= | Silent (SNP) | VAF 20/66 reads (30%) | catalogued as rs765005253, COSV62128579, COSV62128769; called by muse, mutect2, varscan2
- OR10V1 | c.117C>T p.L39= | Silent (SNP) | VAF 89/233 reads (38%) | catalogued as rs778530423, COSV55700323; called by muse, mutect2, varscan2
- PTPN22 | c.1965A>G p.E655= (on ENST00000359785 / NM_001193431.2; = p.E600= on NM_012411.5) | Silent (SNP) | VAF 9/217 reads (4%) | called by muse, mutect2
- RP1 | c.1641C>T p.L547= | Silent (SNP) | VAF 44/134 reads (33%) | called by muse, mutect2, varscan2
- RSPO4 | c.198C>T p.Y66= | Silent (SNP) | VAF 111/625 reads (18%) | catalogued as rs751352700, COSV54081092, COSV54083454; called by muse, mutect2, varscan2
- SLC45A3 | c.867G>A p.T289= | Silent (SNP) | VAF 95/167 reads (57%) | catalogued as rs768335329, COSV65654778; called by muse, mutect2, varscan2
- SLC9B1 | c.165C>T p.Y55= | Silent (SNP) | VAF 20/130 reads (15%) | called by muse, mutect2, varscan2
- SMAD7 | c.522C>T p.V174= | Silent (SNP) | VAF 67/166 reads (40%) | catalogued as rs768564558; called by muse, mutect2, varscan2
- TMPRSS15 | c.198C>T p.S66= | Silent (SNP) | VAF 117/284 reads (41%) | catalogued as rs372549174; called by muse, mutect2, varscan2
- TVP23A | c.33T>C p.D11= | Silent (SNP) | VAF 28/323 reads (9%) | called by muse, mutect2
- AC133561.1 | n.1425G>T | RNA (SNP) | VAF 85/214 reads (40%) | called by mutect2, varscan2
- AC133561.1 | n.1940C>T | RNA (SNP) | VAF 105/275 reads (38%) | catalogued as rs1264852589; called by muse, mutect2, varscan2
- AC244517.10 | c.36-10034G>A | Intron (SNP) | VAF 10/124 reads (8%) | catalogued as COSV73145095; called by muse, mutect2
- ADAM7 | c.*35A>T | 3'UTR (SNP) | VAF 7/48 reads (15%) | called by muse, mutect2, varscan2
- AL353804.6 | chrX:73827971 C>T | 3'Flank (SNP) | VAF 38/38 reads (100%) | called by muse, mutect2
- CLK2P1 | n.816T>C | RNA (SNP) | VAF 26/847 reads (3%) | called by muse, mutect2
- CYP2A7P1 | n.420C>T | RNA (SNP) | VAF 90/885 reads (10%) | called by muse, mutect2, varscan2
- DDX11 | c.-4-204T>C | Intron (SNP) | VAF 11/148 reads (7%) | called by muse, mutect2
- DSC3 | c.2494-120C>A | Intron (SNP) | VAF 12/202 reads (6%) | called by muse, mutect2
- DUX4L8 | n.706C>T | RNA (SNP) | VAF 48/833 reads (6%) | catalogued as rs782032535; called by muse, mutect2
- EGFR | c.1881-744_1881-726del | Intron (DEL) | VAF 2181/14542 reads (15%) | called by mutect2, pindel
- EYS | c.1767-8099C>T | Intron (SNP) | VAF 16/61 reads (26%) | catalogued as rs759234636; called by mutect2, varscan2
- LIG1 | c.1610-27_1610-25del | Intron (DEL) | VAF 38/210 reads (18%) | catalogued as rs1370790654; called by pindel, varscan2
- RACK1 | c.430-648G>T | Intron (SNP) | VAF 8/27 reads (30%) | called by muse, mutect2, varscan2
- RGS2 | c.-20dup | 5'UTR (INS) | VAF 96/357 reads (27%) | called by mutect2, pindel, varscan2
- RN7SL319P | chr15:75782149 C>G | 5'Flank (SNP) | VAF 65/408 reads (16%) | called by muse, varscan2
- SIRPD | c.*18C>T | 3'UTR (SNP) | VAF 49/227 reads (22%) | catalogued as rs749802902, COSV67547419; called by muse, mutect2, varscan2
- SLC9A7P1 | n.364G>A | RNA (SNP) | VAF 113/275 reads (41%) | catalogued as rs763216666; called by muse, mutect2, varscan2
- SNORD116-2 | n.82C>T | RNA (SNP) | VAF 90/205 reads (44%) | catalogued as rs773813521; called by muse, mutect2, varscan2
- SRGAP3 | c.801+80T>C | Intron (SNP) | VAF 73/410 reads (18%) | called by muse, mutect2, varscan2
- TNFRSF1A | c.625+32C>T | Intron (SNP) | VAF 168/418 reads (40%) | catalogued as rs762013205, COSV50598238; called by muse, mutect2, varscan2
